Gene-level copy-number profile of tumor specimen TCGA-2G-AALN-01A from TCGA case TCGA-2G-AALN, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Tissue or organ of origin: Testis, NOS.
Specimen TCGA-2G-AALN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-TGCT.de733352-5f67-474d-b5b7-5a944d2b1d32.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2G-AALN-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/796efc22-16bc-4ae0-b9ae-c70251a3460f

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 1: 248; copy number 2: 24,736; copy number 3: 29,177; copy number 4: 2,091; copy number 5: 2,381; copy number 6: 317; copy number 9: 7; copy number 10: 459; copy number 11: 384.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2G-AALN-01A-11D-A42X-01): tumor purity 0.73, ploidy 2.67, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:59,685,820–60,301,317, 19 genes: AC010776.1, AC010776.2, AC010776.3, RPS26P54, GLUD1P4, AC098847.1, PMAIP1, AC107990.1, NFE2L3P1, RN7SL342P, ENTR1P1, AC090377.1, SINHCAFP2, RNU6-567P, AC090771.2, RPS3AP49, RNU4-17P, AC090771.1, AC090621.1.
- chr18:60,371,062–60,372,775, 1 gene: MC4R.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 850 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:66,767–34,249,958, 850 genes, copy number 9–11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 248. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
